MMRF case MMRF_2216 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0621d93d-1397-443f-9223-04c042927505

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 84 years; Vital status: Dead; Days to death: 406 days (1.1 years).

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 84.3 years (30,785 days); ISS stage: III; Days to last known disease status: 406 days (1.1 years); Days to last follow up: 406 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 12 days; Days to treatment end: 385 days (1.1 years).

Follow-up (1 entry)
- Follow-up contacts recording only the day: day 1, day 406.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1: M Protein 2.5 g/dL; Beta 2 Microglobulin 6.08 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 8.3 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 339 ×10⁹/L; Creatinine 126 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.88 mmol/L; Albumin 43 g/L; Total Protein 8.5 g/dL; Glucose 7.87 mmol/L.
- Day 77 (ECOG 3): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.61 mg/dL; Hemoglobin 5.83 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 111 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.25 mmol/L; Albumin 31 g/L; Total Protein 6.2 g/dL; Glucose 5.78 mmol/L.
- Day 183: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.58 mg/dL; Beta 2 Microglobulin 4.77 µg/mL; Hemoglobin 4.9 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.28 mmol/L; Albumin 31 g/L; Total Protein 5.6 g/dL; Glucose 5.67 mmol/L.
- Day 267 (ECOG 3): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.24 mg/dL; Hemoglobin 6.45 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 28 g/L; Total Protein 5.6 g/dL; Glucose 5.45 mmol/L.
- Day 365 (ECOG 3): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.04 mg/dL; Hemoglobin 6.26 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 121 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 30 g/L; Total Protein 5.2 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day 1: Weight: 62 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_2216_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_2216_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
